BEATAML1.0 case 2368 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/b0c6f482-17b0-4ab1-ad1e-b9bbe47d9a94

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, CBF-beta/MYH11: ICD-O-3 morphology code: 9871/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.5 years (13,345 days); Progression or recurrence: no; ELN risk classification: Favorable.

Biospecimens (3 samples)
- Sample BA2214D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample BA2639D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA2639R: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
